Surgical pathology report (de-identified scan), TCGA case TCGA-K1-A6RU, project TCGA-SARC (Sarcoma), tissue source site University of Pittsburgh, specimen TCGA-K1-A6RU-01A (Primary Tumor).

[page 1 of 2]
Collection Date:

FINAL DIAGNOSIS:

SOFT TISSUE, LEFT POSTERIOR THIGH, RESECTION -

- A. HIGH GRADE MYXOFIBROSARCOMA, GRADE 3, 20.0 CM (see comment).
- B. MITOTIC FIGURES: 26 PER 10 HIGH-POWER FIELDS, NECROSIS: 20%.
- C. MEDIAL, POSTERIOR AND LATERAL RESECTION MARGINS ARE POSITIVE FOR TUMOR; ALL OTHER MARGINS ARE NEGATIVE FOR TUMOR.
- D. NO ANGIOLYMPHATIC INVASION SEEN.
- E. PATHOLOGICAL STAGE: pT2b Nx.
- F. PATHOLOGICAL GRADE: GRADE 3.

IG 0-3
Fibromyxosarcoma 8811/3
Site Soft tissue of thigh
C49.2

COMMENT:

This high grade sarcoma consists of pleomorphic spindled cells in a myxoid and collagenous background with curvilinear vessels. Focal low grade areas are observed. Mitoses of 26 per 10 high power fields and 20% necrosis are noted. The tumor cells are immunoreactive for CD99, calponin, BCL6 and show focal positivity for actin, desmin, pankeratin and CD34. S100 highlights dendritic cells. A Ki67 shows approximately 80% nuclear positivity. FISH studies for CHOP and MDM2 are negative. These results together with the morphology support a high grade sarcoma and are compatible with myxofibrosarcoma.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY SOFT TISSUE TUMORS

SPECIMEN TYPE:	Marginal resection
TUMOR SITE:	posterior left thigh
TUMOR DEPTH:	Deep: Intramuscular
TUMOR SIZE:	Greatest dimension: 20 cm
TUMOR INVOLVEMENT:	Other: skeletal muscle
PRERESECTION TREATMENT:	Unknown
HISTOLOGIC TYPE (WHO classification of soft tissue tumors):	myxofibrosarcoma
RESULTS OF ANCILLARY STUDIES:	see comment
MITOTIC RATE:	26 /10 high-power fields
MACROSCOPIC NECROSIS:	Present: Extent: 20%
MICROSCOPIC NECROSIS:	Present: Extent: 20%
GRADE:	System used: Grade: grade 3
PATHOLOGIC STAGING (pTNM):	pT2b pNX Number regional lymph nodes examined: 0 Number regional lymph nodes involved: 0 pMX
MARGINS:	Margins involved by sarcoma Margin(s): medial, posterior and lateral margins
MICROSCOPIC VENOUS/LYMPHATIC (LARGE/SMALL VESSEL) INVASION:	Absent
PERINEURAL INVASION:	Absent

[page 2 of 2]
SPECIAL PROCEDURES:

In Situ Procedure

Interpretation

PROBE: **DDIT3**

Cytogenetic location: 12q13

Probe description: The two probes are separated by approximately 56 kb gap within the **DDIT3** gene.

DDIT3 FISH STUDIES ARE NEGATIVE FOR TRANSLOCATION.

Total # cells analyzed: 62

% cells positive for translocation: 0(0%)

% cells negative for translocation: 62(100%)

Probe: **MDM2/CEP12**

MDM2 clones

Cytogenetic Location: 12q15/12p11.1q11.1

MDM2 FISH STUDIES PERFORMED ARE NEGATIVE FOR AMPLIFICATION.

of cells analyzed: 60

Ratio: 0.93

SNR: 1.9

This result should be integrated with all clinical and pathologic data in the determination of a comprehensive diagnostic and treatment plan.

Results

DDIT3 translocation detection is as follows: Normal cells without the **DDIT3** translocation show green and orange signals in juxtaposition. Cells with the **DDIT3** translocation show one pair of signals (green and orange) in juxtaposition and one green and one orange signal separated.

DDIT3 FISH analysis was manually performed and quantitatively assessed by analysis of a minimum of 60 cells using the **DDIT3** (centromeric) and (telomeric) probes.

MDM2 FISH analysis was manually performed and quantitatively assessed by analysis of a minimum of 60 cells using the **MDM2** and the **CEP12** probes.

Source: NCI Genomic Data Commons file f6d8fe47-3504-4893-8262-c65d740268b1 (TCGA-K1-A6RU.645EC87E-34E7-45E8-BA8D-2F06269F7060.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).